Gene-level copy-number profile of specimen HCM-CSHL-0820-C34-85B from HCMI case HCM-CSHL-0820-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Non-small cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: GX; Age at diagnosis: 70.8 years (25,843 days).
Specimen HCM-CSHL-0820-C34-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ddd722e5-a710-4b65-b5fb-b63424030c4b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0820-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/510ad32f-eaa0-4101-b10a-76acac36a559

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 283; copy number 2: 17,155; copy number 3: 29,779; copy number 4: 7,302; copy number 5: 3,469; copy number 6: 122; copy number 7: 155; copy number 8: 2; copy number 9: 3; copy number 10: 1; copy number 11: 1; copy number 13: 2; copy number 14: 1; copy number 27: 23; copy number 28: 1; copy number 39: 7; copy number 44: 2; copy number 47: 2; copy number 52: 5; copy number 55: 1; copy number 56: 1; copy number 57: 1; copy number 61: 6; copy number 63: 3; copy number 64: 5; copy number 68: 15; copy number 81: 3; copy number 100: 3; copy number 106: 6; copy number 135: 12.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:42,183,659–42,354,454, 5 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.
- chr21:9,068,361–9,129,752, 3 genes: TEKT4P2, SOWAHCP2, CR392039.2.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–2): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 261 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:143,336,762–144,870,953, 19 genes, copy number 27 (within-gene range 3–27): GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1, AC107223.1, GUSBP5, FREM3, AC104090.1, GYPE, AC093890.1, GYPB, AC093890.2, GYPA, AC098588.3.
- chr4:144,505,900–144,745,271, 4 genes, copy number 27 (within-gene range 3–27): AC106871.1, KRT18P51, HHIP-AS1, HHIP.
- chr7:47,608,465–47,661,648, 2 genes, copy number 44: LINC01447, C7orf65.
- chr7:54,542,325–55,255,635, 12 genes, copy number 52–100: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr7:55,731,100–55,955,239, 15 genes, copy number 68 (within-gene range 4–68): Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713.
- chr7:56,228,634–56,305,526, 3 genes, copy number 63: CCNJP1, AC073136.1, AC073136.2.
- chr8:47,202,444–47,738,164, 8 genes, copy number 8–106: IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD.
- chr8:127,578,473–128,220,803, 15 genes, copy number 81–135: AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr14:21,585,290–22,559,037, 144 genes, copy number 7 (broad region; genes not listed).
- chr14:35,897,936–36,068,261, 1 gene, copy number 7 (within-gene range 5–7): AL133304.3.
- chr14:36,054,197–36,067,190, 2 genes, copy number 7: ILF2P2, AL133304.2.
- chr14:36,320,753–36,656,163, 1 gene, copy number 61 (within-gene range 5–61): AL132857.1.
- chr14:36,473,207–36,534,538, 5 genes, copy number 61: SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2.
- chr14:36,647,083–37,552,361, 10 genes, copy number 28–56 (within-gene range 6–56): AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1.
- chr14:37,556,158–37,596,059, 3 genes, copy number 47–57 (within-gene range 5–57): AL121790.2, AL121790.1, FOXA1.
- chr16:32,250,620–32,265,514, 3 genes, copy number 7–9: AC133485.3, TP53TG3D, AC133485.2.
- chr16:32,388,135–32,441,159, 2 genes, copy number 7–8: AC138915.2, PABPC1P13.
- chr16:32,475,051–32,615,639, 2 genes, copy number 9–10: ABCD1P3, AC137800.1.
- chr16:32,877,469–32,903,894, 3 genes, copy number 11–13: SLC6A10P, AC142086.1, IGHV3OR16-15.
- chr22:18,422,244–18,527,626, 6 genes, copy number 7: FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3.
- chr22:18,733,914–18,757,906, 1 gene, copy number 14: FAM230E.

Autosomal genes at a single copy (total copy number 1): 283. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
